Surgical pathology report (de-identified scan), TCGA case TCGA-GV-A3QH, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - Cleveland Clinic, specimen TCGA-GV-A3QH-01A (Primary Tumor).

[page 1 of 2]
Encounter Date: [REDACTED]

SURGICAL PATHOLOGY (Order [REDACTED])

Patient Name [REDACTED]

Sex [REDACTED]

DOB [REDACTED]

Results

Specimen #: [REDACTED]
Submitting Physician: [REDACTED]

ICD-O-3
carcinoma, urothelial, NOS
8120/3
Site: bladder, trigone
2-29-12 EP 607.0

FINAL DIAGNOSIS

Tumor, left hemi-trigone, transurethral resection - Invasive high-grade urothelial carcinoma with focal squamous differentiation.
- The neoplasm invades into the muscularis propria (detrusor muscle).

COMMENT

Procedure: TURBT

Histologic Type: Urothelial (transitional cell) carcinoma with squamous differentiation

Associated Epithelial Lesions: None identified

Histologic Grade: (Urothelial Carcinoma (WHO /)): High-grade

Tumor Configuration: Invasive

Adequacy of Material for Determining Muscularis Propria Invasion:
Muscularis propria (detrusor muscle) present

Lymph-Vascular Invasion: Not identified

Microscopic Extent of Tumor: Tumor invades muscularis propria (detrusor muscle)

Additional Pathologic Findings: None

(Electronic Signature)

SPECIMEN SUBMITTED

A: TUMOR LEFT HEMI-TRIGONE

CLINICAL DATA

BLADDER CA

GROSS DESCRIPTION

A. Received fresh are multiple fragments of tan-pink rubbery soft tissue

HRpA Discrepancy		
Reviewer Initials: M6	Date Reviewed: 2/20/12	

[page 2 of 2]
aggregating to 3.0 x 2.0 x 0.7 cm and weighing 1.5 grams. Totally submitted in two cassettes.

Patient ID #: [REDACTED]
DOB: [REDACTED] (Age: [REDACTED])
Date of Report: [REDACTED]
Date of Procedure: [REDACTED]
Date of Receipt: [REDACTED]
Submitted by: [REDACTED]
Location: [REDACTED]
Test performed by: [REDACTED]

Lab and Collection

SURGICAL PATHOLOGY (Order [REDACTED] on [REDACTED] - Lab and Collection Information

Result History

SURGICAL PATHOLOGY (Order [REDACTED] on [REDACTED] - Order Result History Report

Result Information

Result Date and Time	Status	Provider Status
[REDACTED]	Final result	Reviewed

MyChart Status:

This result is currently not released to

[Display Full Result Report](#)

[Display Order Report](#)

Source: NCI Genomic Data Commons file 01a64b87-2f5b-4086-ad6d-e0afe620b793 (TCGA-GV-A3QH.7492187D-9243-482E-B2A0-08CAD7EB7DBE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).